Gene-level copy-number profile of tumor specimen TCGA-M7-A721-01A from TCGA case TCGA-M7-A721, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.0 years (25,585 days).
Specimen TCGA-M7-A721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.fa3b0951-6a36-468f-b541-e873be049c2a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-M7-A721-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2566c6d0-cae3-438a-976a-ecd5dd781d68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,769; copy number 1: 3,954; copy number 2: 52,332; copy number 3: 179; copy number 5: 4; copy number 6: 3; copy number 7: 3; copy number 8: 4; copy number 10: 2; copy number 14: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-M7-A721-01A-12D-A32A-01): tumor purity 0.24, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1,382 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,370,448–75,580,199, 11 genes: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr4:114,598,770–115,143,303, 6 genes: UGT8, MIR577, CIR1P2, RN7SL808P, NDST4, MRPS33P3.
- chr4:126,431,694–126,735,523, 2 genes: AC097528.1, RBM48P1.
- chr5:97,799,404–100,903,282, 52 genes (within-gene range 0–2): AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.
- chr6:285,443–351,355, 2 genes: AL365272.1, DUSP22.
- chr6:84,421,028–84,556,152, 1 gene (within-gene range 0–1): LINC01611.
- chr6:84,687,351–90,587,072, 113 genes (broad region; genes not listed).
- chr6:119,327,281–123,685,323, 44 genes: RNU6-194P, AL078600.1, MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1.
- chr10:85,156,330–105,265,242, 478 genes (within-gene range 0–12) (broad region; genes not listed).
- chr11:101,451,564–102,110,457, 10 genes: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2.
- chr11:109,637,468–123,228,502, 359 genes (broad region; genes not listed).
- chr12:23,108,458–23,108,493, 1 gene: AC087258.1.
- chr13:41,061,509–57,729,311, 301 genes (broad region; genes not listed).
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr18:1,780,329–1,782,064, 1 gene: AP005057.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes, copy number 10: CFHR3, CFHR1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 14 (within-gene range 2–14): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 14: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr4:68,509,441–68,616,137, 4 genes, copy number 8: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr12:31,073,860–31,254,445, 6 genes, copy number 6–7: DDX11, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1.

Autosomal genes at a single copy (total copy number 1): 3,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
